Somatic mutation profile of tumor specimen TCGA-YU-AA4L-01A (aliquot TCGA-YU-AA4L-01A-11D-A435-10) from TCGA case TCGA-YU-AA4L, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 27.1 years (9,902 days).
Specimen TCGA-YU-AA4L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 781808ce-fc31-4295-ad11-1de4bd974d01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YU-AA4L-10A (Blood Derived Normal), aliquot TCGA-YU-AA4L-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/befd736d-95fb-41f1-9332-177f4c934053

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'UTR 2, Silent 2, Nonsense Mutation 1, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT4 | c.10676A>G p.Y3559C | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV100629322; called by muse, mutect2, varscan2
- FLG | c.3643A>C p.S1215R | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV100910503, COSV64238953, COSV64251096; called by muse, mutect2
- MUC5B | c.12037G>A p.G4013R | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.313); catalogued as rs373617983; called by muse, mutect2, varscan2
- SIL1 | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as CM1312512, COSV54534844; called by muse, mutect2
- GBP3 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 76/267 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HMG20B | c.449_460del p.I150_K153del | In Frame Del (DEL) | VAF 12/30 reads (40%) | called by mutect2, varscan2
- HRH3 | c.878dup p.G294Wfs*22 | Frame Shift Ins (INS) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- SART1 | c.1778A>C p.N593T | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT tolerated (0.58); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SPC24 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2
- UACA | c.2317_2318del p.Q773Kfs*17 | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | called by pindel, varscan2
- CPAMD8 | c.3100T>C p.L1034= (on ENST00000651564; = p.L987= on NM_015692.5) | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs1447579545; called by muse, mutect2, varscan2
- ZNF217 | c.1168C>T p.L390= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs779976099; called by muse, mutect2, varscan2
- LHX9 | c.-277G>A | 5'UTR (SNP) | VAF 38/144 reads (26%) | catalogued as COSV100435901; called by muse, mutect2, varscan2
- NIP7 | c.-9G>T | 5'UTR (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
